Somatic mutation profile of tumor specimen 0DVXFI from CCDI case PBCMTT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 20.8 years (7,614 days).
Specimen 0DVXFI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dc9e9f6-646c-411f-9310-bbee6eb16770.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVXFN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b90fd528-72d7-4d7a-b737-630a78f586da

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 1, In Frame Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCNP | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 28/514 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1483615458, COSV55688560; called by muse, mutect2
- CHRNA7 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.086); catalogued as rs1339828163; called by mutect2, varscan2
- GJB6 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355233247; called by muse, mutect2
- HAPLN3 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.025); catalogued as rs778779992, COSV62084822; called by muse, mutect2
- MBD1 | c.1747C>G p.R583G (on ENST00000269468 / NM_001323950.1; = p.R481G on NM_002384.2) | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1232210734, COSV54006175; called by muse, mutect2
- OAS2 | c.1508A>G p.Y503C | Missense Mutation (SNP) | VAF 126/378 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60804719; called by muse, mutect2, varscan2
- ATP10D | c.3244G>C p.V1082L | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- SOX10 | c.513_521dup p.Y173_Q174insHKY | In Frame Ins (INS) | VAF 152/417 reads (36%) | called by mutect2, varscan2
- TAF1 | c.335del p.Q112Rfs*24 | Frame Shift Del (DEL) | VAF 132/210 reads (63%) | called by mutect2, pindel, varscan2
- TMEM132C | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 40/494 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2
- LINGO3 | c.736C>T p.L246= | Silent (SNP) | VAF 89/189 reads (47%) | called by muse, mutect2, varscan2
- RBM3 | c.103+20C>T | Intron (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
